Gene-level copy-number profile of tumor specimen ALCH-B0AJ-TTP1-A from ALCHEMIST case ALCH-B0AJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,288 days).
Specimen ALCH-B0AJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba9e41bb-d8ca-4bd3-9ff6-d5d7371fec63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/676b6ca4-1496-4a16-b511-6dcca4d18016

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 4,016; copy number 2: 46,995; copy number 3: 5,038; copy number 4: 131; copy number 5: 2,192; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:76,992,099–76,993,108, 1 gene: AL353637.1.
- chr12:80,099,537–80,380,879, 1 gene (within-gene range 0–2): OTOGL.
- chr12:80,343,515–80,343,792, 1 gene (within-gene range 0–2): RN7SKP261.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,194 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:36,483,769–36,510,537, 2 genes, copy number 9: TRAF6, AC061999.1.
- chr15:19,878,555–101,979,093, 2,192 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,698. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
